Somatic mutation profile of tumor specimen TCGA-33-4532-01A (aliquot TCGA-33-4532-01A-01D-1267-08) from TCGA case TCGA-33-4532, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.9 years (25,169 days).
Specimen TCGA-33-4532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 286a5b6d-2d73-40e0-90eb-fa9b36fb5f33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-4532-11A (Solid Tissue Normal), aliquot TCGA-33-4532-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b41ce41-c783-4d65-8260-cbf5576f41ff

The open-access MAF lists 395 somatic variants for this specimen: 291 protein-altering or splice-affecting, 86 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 256, Silent 86, Nonsense Mutation 22, RNA 8, Intron 6, Splice Site 6, Frame Shift Del 3, 5'UTR 2, 3'Flank 1, 3'UTR 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4348T>G p.Y1450D | Missense Mutation (SNP) | VAF 28/74 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM050569, COSV52117114, COSV52136038; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 114/167 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11783A>G p.D3928G | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV71284860; called by muse, mutect2, varscan2
- ABCA2 | c.7291C>T p.R2431W (on ENST00000614293; = p.R2401W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.663); catalogued as rs1446325593, COSV55799205; called by muse, mutect2, varscan2
- ABCA2 | c.2800G>T p.A934S (on ENST00000614293; = p.A904S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/192 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV55799213; called by muse, varscan2
- ABCA9 | c.4635G>T p.Q1545H | Missense Mutation (SNP) | VAF 193/236 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60622313; called by muse, mutect2, varscan2
- ABCB8 | c.2057G>A p.R686H (on ENST00000297504 / NM_001282291.2; = p.R669H on NM_007188.5) | Missense Mutation (SNP) | VAF 94/353 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs546942647, COSV52503194; called by muse, mutect2, varscan2
- ADAD1 | c.1169C>G p.T390S | Missense Mutation (SNP) | VAF 79/355 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as COSV56642381; called by muse, mutect2, varscan2
- ADAM18 | c.1903-1G>T p.X635_splice | Splice Site (SNP) | VAF 16/25 reads (64%) | catalogued as COSV55845356; called by muse, mutect2, varscan2
- ADARB2 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV67218464; called by muse, mutect2, varscan2
- ADGRG5 | c.746C>A p.T249K | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs371516015, COSV61082848; called by muse, varscan2
- ADRA1D | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs890664407, COSV65240431; called by muse, mutect2, varscan2
- AFF3 | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 50/446 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs775211684, COSV57845950; called by muse, mutect2, varscan2
- AIPL1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 326/431 reads (76%) | catalogued as COSV51506273; called by muse, mutect2, varscan2
- AKAP11 | c.3416C>G p.S1139C | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766418968, COSV50294184; called by muse, mutect2, varscan2
- AKAP13 | c.267T>A p.F89L | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV63452042; called by muse, mutect2
- AKAP13 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV63452058; called by muse, mutect2
- ALDH1L2 | c.1208C>A p.T403N | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.551); catalogued as rs1264587183, COSV51554358; called by muse, mutect2, varscan2
- ALMS1 | c.8665G>C p.E2889Q | Missense Mutation (SNP) | VAF 368/625 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52505708; called by muse, mutect2, varscan2
- ANKRD52 | c.919A>G p.K307E | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV57283260; called by muse, mutect2, varscan2
- ANKRD7 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 256/590 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.453); catalogued as COSV54554182, COSV54554738; called by muse, mutect2, varscan2
- ANTXR1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs768355159, COSV100363270, COSV58010898; called by muse, mutect2
- AP3B2 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV55607748; called by muse, mutect2, varscan2
- APOB | c.4384G>A p.G1462R | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51928499; called by muse, mutect2
- ARSL | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66964978; called by muse, mutect2, varscan2
- ASIC3 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV52521127; called by muse, mutect2, varscan2
- ASPHD2 | c.662A>T p.N221I | Missense Mutation (SNP) | VAF 111/584 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV53218475; called by muse, mutect2, varscan2
- ATP11C | c.2014A>T p.K672* | Nonsense Mutation (SNP) | VAF 26/157 reads (17%) | catalogued as COSV59560823; called by muse, mutect2, varscan2
- ATP13A4 | c.2866A>T p.K956* | Nonsense Mutation (SNP) | VAF 214/252 reads (85%) | catalogued as COSV61317798; called by muse, mutect2, varscan2
- ATP13A4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 38/596 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs1560280711, COSV55067443; called by muse, mutect2
- ATP2B4 | c.3145A>G p.I1049V | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.059); catalogued as rs1265818922, COSV58175495; called by muse, mutect2, varscan2
- ATP8B1 | c.3317G>A p.S1106N | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1568178477, COSV52173796; called by muse, mutect2, varscan2
- BAZ1A | c.3409G>C p.D1137H | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV62409532; called by muse, mutect2, varscan2
- BCAN | c.1922T>A p.V641E | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.617); catalogued as COSV61255927; called by muse, mutect2, varscan2
- BMS1 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 83/209 reads (40%) | catalogued as COSV65733225; called by muse, mutect2, varscan2
- BRINP3 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV66517300, COSV66523379; called by muse, mutect2
- C20orf27 | c.458G>T p.G153V (on ENST00000379772 / NM_001258429.2; = p.G178V on NM_001039140.3) | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53923417; called by muse, mutect2, varscan2
- CASP9 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61601107; called by muse, mutect2, varscan2
- CCDC146 | c.2358C>A p.D786E | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV53545672; called by muse, mutect2
- CCSAP | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV52909254; called by muse, mutect2
- CDHR1 | c.1367C>G p.A456G | Missense Mutation (SNP) | VAF 202/435 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60560587; called by muse, mutect2, varscan2
- CEP112 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 122/170 reads (72%) | SIFT tolerated (0.44); PolyPhen benign (0.248); catalogued as COSV67137522; called by muse, mutect2, varscan2
- CEP126 | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs537245238, COSV54823124; called by muse, mutect2, varscan2
- CEP128 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 97/221 reads (44%) | catalogued as COSV55371576; called by muse, mutect2, varscan2
- CEP55 | c.812A>G p.E271G | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV65184763; called by muse, mutect2, varscan2
- CFAP74 | c.189G>T p.L63F | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.275); catalogued as COSV54565757, COSV54567361, COSV54575264; called by muse, mutect2, varscan2
- CHAT | c.1093A>T p.R365W | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60322062; called by muse, mutect2, varscan2
- CHD7 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 43/440 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV71108068; called by muse, mutect2, varscan2
- CLASP1 | c.4153G>A p.A1385T | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV55318031; called by muse, mutect2
- CLASP2 | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 67/81 reads (83%) | catalogued as COSV56278523; called by muse, mutect2, varscan2
- CLASP2 | c.2436G>C p.E812D | Missense Mutation (SNP) | VAF 67/81 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56278561; called by muse, mutect2, varscan2
- CLEC12A | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV58560846; called by muse, mutect2, varscan2
- CLMN | c.57C>A p.S19R | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV54180342; called by muse, mutect2
- CNGB3 | c.2206G>C p.E736Q | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.055); catalogued as COSV60686699; called by muse, mutect2, varscan2
- CNTNAP4 | c.3781G>C p.A1261P | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV56671100; called by muse, mutect2, varscan2
- COA6 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV64016762; called by muse, varscan2
- COL19A1 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59568630; called by muse, mutect2, varscan2
- COL22A1 | c.1162C>A p.L388I | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1239696685, COSV57329270; called by muse, mutect2, varscan2
- COL26A1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.746); catalogued as COSV58122143; called by muse, mutect2
- COPA | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54099898; called by muse, mutect2, varscan2
- CPB2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 187/292 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51673001, COSV51675021; called by muse, mutect2, varscan2
- CPZ | c.1859G>T p.R620L (on ENST00000360986 / NM_001014447.3; = p.R609L on NM_003652.3) | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV59921609, COSV59922101; called by muse, mutect2, varscan2
- CSF3R | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 97/175 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58964732; called by muse, mutect2, varscan2
- CSMD2 | c.1717G>C p.G573R | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.756); catalogued as COSV53891419; called by muse, mutect2, varscan2
- CTNND2 | c.1744A>C p.N582H | Missense Mutation (SNP) | VAF 206/441 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58874375; called by muse, mutect2, varscan2
- CUBN | c.1175G>T p.C392F | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100911816, COSV64710896; called by muse, mutect2
- CXorf66 | c.1048T>A p.Y350N | Missense Mutation (SNP) | VAF 91/118 reads (77%) | SIFT tolerated (0.31); PolyPhen benign (0.241); catalogued as COSV65169001; called by muse, mutect2, varscan2
- DAAM1 | c.2524A>G p.K842E | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs948387898, COSV62835045; called by muse, mutect2, varscan2
- DACT1 | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60019973; called by muse, mutect2, varscan2
- DCAF5 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs769304455, COSV58459289; called by muse, mutect2, varscan2
- DDX1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV51838770; called by muse, mutect2, varscan2
- DENND1A | c.508A>T p.R170* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV65323797; called by muse, mutect2, varscan2
- DENND2A | c.1064A>C p.Q355P | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV52049027; called by muse, mutect2, varscan2
- DNAH11 | c.5496A>T p.Q1832H | Missense Mutation (SNP) | VAF 231/498 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60946739; called by muse, mutect2, varscan2
- DNAH7 | c.2733G>T p.E911D | Missense Mutation (SNP) | VAF 104/298 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.324); catalogued as COSV56756797; called by muse, varscan2
- DNAH7 | c.2732A>G p.E911G | Missense Mutation (SNP) | VAF 106/303 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV56756805; called by muse, varscan2
- DNAH8 | c.1835C>G p.T612S | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.604); catalogued as COSV59433482; called by muse, mutect2, varscan2
- DNAH8 | c.9159T>A p.Y3053* | Nonsense Mutation (SNP) | VAF 29/98 reads (30%) | catalogued as COSV59433497; called by muse, mutect2, varscan2
- DNAI4 | c.838A>T p.R280* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as COSV64018064; called by muse, mutect2, varscan2
- DOCK3 | c.1326G>T p.K442N | Missense Mutation (SNP) | VAF 112/145 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56508325; called by muse, mutect2, varscan2
- DOCK4 | c.3932G>T p.R1311L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69854322; called by muse, mutect2, varscan2
- DOCK5 | c.2627A>T p.E876V | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs934876948, COSV52398068; called by muse, mutect2, varscan2
- DPP10 | c.2370G>T p.Q790H | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.375); catalogued as COSV59673967; called by muse, mutect2, varscan2
- DPP10 | c.2371G>T p.E791* | Nonsense Mutation (SNP) | VAF 36/128 reads (28%) | catalogued as COSV59673986, COSV59737448; called by muse, mutect2, varscan2
- DPY19L1 | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV60581440; called by muse, varscan2
- DSCAML1 | c.4001G>A p.G1334D (on ENST00000321322; = p.G1274D on NM_020693.4) | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58385613; called by muse, mutect2, varscan2
- DUOX2 | c.4383G>T p.R1461S | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66531232; called by muse, mutect2, varscan2
- DZANK1 | c.1915G>C p.E639Q (on ENST00000262547 / NM_001099407.1; = p.E446Q on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/451 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.095); catalogued as COSV52749191; called by muse, mutect2, varscan2
- EFS | c.1424A>G p.K475R | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52835130; called by muse, mutect2, varscan2
- ELL3 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 35/191 reads (18%) | catalogued as COSV55855181; called by muse, mutect2, varscan2
- EPHA3 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs766046211, COSV60698582; called by muse, mutect2, varscan2
- EPHA6 | c.2972C>T p.A991V | Missense Mutation (SNP) | VAF 87/122 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67564734; called by muse, mutect2, varscan2
- EPHA8 | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV51264886; called by muse, mutect2, varscan2
- ERICH3 | c.2750A>G p.H917R | Missense Mutation (SNP) | VAF 28/538 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs982998101, COSV58602314; called by muse, mutect2
- ESRRB | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.911); catalogued as COSV55059780; called by muse, mutect2, varscan2
- EXOC5 | c.2005G>T p.D669Y | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61770440; called by muse, mutect2, varscan2
- EZH1 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 172/223 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70548955; called by muse, mutect2, varscan2
- FMO2 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52947111; called by muse, mutect2
- FOLH1 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57047102; called by muse, mutect2
- FRG2B | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 29/507 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.482); catalogued as rs1355934663, COSV71042760; called by muse, mutect2
- GAPVD1 | c.4195A>G p.R1399G (on ENST00000394104; = p.R1408G on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/214 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52921678; called by muse, mutect2, varscan2
- GGTLC1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 188/629 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV53846823; called by muse, mutect2, varscan2
- GHRHR | c.197C>A p.P66Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577536745, COSV58195942; called by muse, mutect2
- GLRB | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52414668; called by muse, mutect2, varscan2
- GOLIM4 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 44/734 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV58328540; called by muse, mutect2
- GPATCH8 | c.1753A>G p.R585G | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV59193794; called by muse, mutect2
- GPC5 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100996217, COSV65586209; called by muse, varscan2
- GPC5 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV65586215; called by muse, mutect2, varscan2
- GPRC5C | c.1186+1G>T p.X396_splice (on ENST00000652232; = p.X351_splice on NM_018653.4) | Splice Site (SNP) | VAF 18/237 reads (8%) | catalogued as COSV61236069; called by muse, mutect2
- GRIN2B | c.2718G>C p.K906N | Missense Mutation (SNP) | VAF 191/532 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74205197; called by muse, varscan2
- GRIN2B | c.2639G>C p.R880P | Missense Mutation (SNP) | VAF 132/395 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV74205198, COSV74206925; called by muse, varscan2
- HCN1 | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 110/277 reads (40%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.334); catalogued as rs1221257807, COSV57496411, COSV57526158; called by muse, mutect2, varscan2
- HNF1A | c.814C>A p.R272S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM082859, CM991168, COSV57459326, COSV57462785; called by muse, mutect2
- HOOK3 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56880250; called by muse, mutect2, varscan2
- HOXC6 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV54536531; called by muse, mutect2, varscan2
- HSPA1L | c.1603A>T p.R535W | Missense Mutation (SNP) | VAF 248/570 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65150003; called by muse, mutect2, varscan2
- HSPB8 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 130/840 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.217); catalogued as COSV99931424; called by muse, varscan2
- HTT | c.5182G>A p.E1728K | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV61859247; called by muse, mutect2, varscan2
- HUWE1 | c.10447A>G p.T3483A | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV53338931; called by mutect2, varscan2
- IFNA6 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 112/301 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV66506292; called by muse, mutect2, varscan2
- IGSF9B | c.3091C>A p.P1031T | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV58065196; called by muse, mutect2, varscan2
- IQSEC3 | c.1485G>C p.Q495H (on ENST00000538872 / NM_001170738.2; = p.Q192H on NM_015232.1) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100407162, COSV58282208; called by muse, mutect2
- IRGC | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs199780198, COSV54983363; called by muse, mutect2, varscan2
- IRX6 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 38/111 reads (34%) | catalogued as COSV51859664; called by muse, mutect2, varscan2
- ITGAX | c.1721G>A p.G574D | Missense Mutation (SNP) | VAF 64/446 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51643526; called by mutect2, varscan2
- KANSL2 | c.543A>T p.L181= | Splice Region (SNP) | VAF 122/175 reads (70%) | catalogued as COSV63479517; called by muse, mutect2, varscan2
- KBTBD7 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1263293760, COSV101068191; called by muse, mutect2
- KCNA2 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 74/274 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60369478; called by muse, mutect2, varscan2
- KDM4B | c.1625A>T p.Q542L | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV50211964; called by muse, varscan2
- KDM4B | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 65/96 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV50212005; called by muse, varscan2
- KDM4C | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 142/252 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1282458478, COSV67184568; called by muse, mutect2, varscan2
- KDM5A | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV66991135; called by muse, mutect2, varscan2
- KIAA1210 | c.1167C>A p.F389L | Missense Mutation (SNP) | VAF 65/73 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68176184; called by muse, mutect2, varscan2
- KIF2B | c.1880C>G p.A627G | Missense Mutation (SNP) | VAF 186/227 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs551246333, COSV52128271, COSV52131947; called by muse, mutect2, varscan2
- KLF2 | c.910T>C p.C304R | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50179584; called by muse, mutect2, varscan2
- KPNA4 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs918558955, COSV62075104; called by muse, mutect2, varscan2
- KRT2 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.879); catalogued as COSV59009602; called by muse, mutect2, varscan2
- KRT73 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV59838431; called by muse, mutect2, varscan2
- LGI2 | c.374C>G p.S125* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV66122595; called by muse, mutect2, varscan2
- LILRB5 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV60255797; called by muse, mutect2, varscan2
- LRRC32 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV52632151; called by muse, mutect2, varscan2
- LRRK1 | c.4440C>G p.I1480M | Missense Mutation (SNP) | VAF 58/1168 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV52605749; called by muse, mutect2
- MACF1 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 97/614 reads (16%) | catalogued as COSV58365169; called by muse, mutect2, varscan2
- MAD1L1 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 125/369 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56229779; called by muse, mutect2, varscan2
- MAD1L1 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 130/374 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as rs1160799280, COSV56229786; called by muse, mutect2, varscan2
- MAGEA4 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.136); catalogued as COSV52340683; called by muse, mutect2, varscan2
- MAGEA6 | c.920G>C p.W307S | Missense Mutation (SNP) | VAF 271/324 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV61448793; called by muse, mutect2, varscan2
- MBD1 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV53999272; called by muse, mutect2, varscan2
- MCM5 | c.294+1G>T p.X98_splice | Splice Site (SNP) | VAF 58/192 reads (30%) | catalogued as COSV53345449; called by muse, mutect2, varscan2
- MDGA2 | c.2572G>T p.D858Y (on ENST00000399232 / NM_001113498.2; = p.D560Y on NM_182830.4) | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62083309; called by muse, mutect2, varscan2
- MESP2 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59092273; called by muse, mutect2, varscan2
- MFHAS1 | c.2041C>A p.L681I | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as COSV52280740; called by muse, mutect2, varscan2
- MIOX | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV53312273; called by muse, mutect2, varscan2
- MMP8 | c.935G>C p.R312T | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52631331; called by muse, mutect2, varscan2
- MMRN1 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 62/85 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV53335130; called by muse, mutect2, varscan2
- MTRR | c.1924G>T p.V642F (on ENST00000264668; = p.V615F on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV52942412; called by muse, mutect2, varscan2
- MTUS1 | c.3119T>G p.L1040* (on ENST00000262102 / NM_001363061.1; = p.L206* on NM_020749.4) | Nonsense Mutation (SNP) | VAF 66/92 reads (72%) | catalogued as COSV50552419; called by muse, mutect2, varscan2
- MYEF2 | c.1790A>G p.D597G | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51046643; called by muse, mutect2, varscan2
- MYH1 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV56845443; called by muse, mutect2
- MYH13 | c.2396A>C p.Y799S | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV52823208; called by muse, mutect2, varscan2
- MYH15 | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs372618528, COSV56306530; called by muse, mutect2, varscan2
- MYO16 | c.3444G>T p.Q1148H | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV62747245; called by muse, mutect2, varscan2
- MYO7B | c.4846T>A p.Y1616N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV67345766; called by muse, mutect2, varscan2
- NAV3 | c.4480C>G p.P1494A | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57069044; called by muse, mutect2, varscan2
- NCAM1 | c.2539G>A p.D847N (on ENST00000316851 / NM_181351.5; = p.D837N on NM_000615.7) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV57513092; called by muse, mutect2, varscan2
- NCAPG | c.1526G>T p.C509F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV52269247; called by muse, mutect2, varscan2
- NECTIN3 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV60550368; called by muse, mutect2
- NEU1 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as COSV57666492; called by muse, mutect2, varscan2
- NLGN1 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 54/419 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV100850172, COSV64324157, COSV64327004; called by muse, mutect2, varscan2
- NLRP5 | c.1868A>T p.Q623L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV66763054; called by muse, mutect2, varscan2
- NLRP7 | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 37/237 reads (16%) | catalogued as rs758004265, COSV60172054; called by muse, mutect2, varscan2
- NLRP8 | c.2397G>T p.L799F | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52584973; called by muse, mutect2, varscan2
- NPC1 | c.1795C>G p.L599V | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV52577357; called by muse, mutect2
- NR2C1 | c.1789C>G p.Q597E | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV60690176; called by muse, mutect2, varscan2
- NRBF2 | c.248G>T p.R83I | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV53258734; called by muse, mutect2, varscan2
- NSUN3 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1318637946, COSV58934559; called by muse, mutect2
- NT5C1A | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.029); catalogued as COSV52493673; called by muse, mutect2, varscan2
- OPCML | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV100105401, COSV59411761; called by muse, mutect2, varscan2
- OR10H1 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 189/250 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771720675, COSV58470679; called by muse, mutect2, varscan2
- OR2M7 | c.794A>T p.H265L | Missense Mutation (SNP) | VAF 106/232 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs773693585, COSV58738371; called by muse, mutect2, varscan2
- OR51B2 | c.209T>G p.M70R | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV60916230; called by muse, mutect2, varscan2
- OR9A2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV63306405; called by muse, mutect2, varscan2
- ORC5 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV52397419; called by muse, mutect2, varscan2
- OTOF | c.5373G>A p.W1791* (on ENST00000272371 / NM_194248.3; = p.W1024* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 18/564 reads (3%) | catalogued as COSV55498977, COSV55514609; called by muse, mutect2
- OXCT1 | c.922A>G p.R308G | Missense Mutation (SNP) | VAF 121/235 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52168713; called by muse, mutect2, varscan2
- PARD3 | c.3137C>T p.S1046F | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV61051411; called by muse, mutect2, varscan2
- PCDH11Y | c.1501T>A p.S501T (on ENST00000400457 / NM_032973.2; = p.S490T on NM_032971.3) | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.129); catalogued as COSV53077278; called by muse, mutect2, varscan2
- PDHA2 | c.974G>T p.S325I | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.906); catalogued as COSV54777948; called by muse, mutect2, varscan2
- PDIA3 | c.1267-1G>T p.X423_splice | Splice Site (SNP) | VAF 14/118 reads (12%) | catalogued as COSV55855167; called by muse, mutect2, varscan2
- PDIA3 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55855176; called by muse, mutect2
- PEG3 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55628934; called by muse, mutect2, varscan2
- PEG3 | c.153C>A p.N51K | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV55628945; called by muse, mutect2, varscan2
- PHF14 | c.2030G>A p.S677N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV68854687; called by muse, mutect2, varscan2
- PLCL1 | c.1991G>C p.C664S | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV70823562; called by muse, mutect2, varscan2
- PLEKHH3 | c.219-1G>A p.X73_splice | Splice Site (SNP) | VAF 55/101 reads (54%) | catalogued as COSV53188380; called by muse, mutect2, varscan2
- PPFIA2 | c.860T>C p.M287T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.838); catalogued as rs778590646, COSV100334677, COSV61024930; called by muse, mutect2, varscan2
- PRAMEF10 | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs201196797; called by mutect2, varscan2
- PREX1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1305893746, COSV64249517; called by muse, mutect2, varscan2
- PRG4 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 109/445 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV66600220; called by muse, mutect2, varscan2
- PROK1 | c.247A>T p.N83Y | Missense Mutation (SNP) | VAF 109/222 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV54764591; called by muse, mutect2, varscan2
- PROZ | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1423930677, COSV61439060; called by muse, mutect2, varscan2
- QSER1 | c.1222G>C p.E408Q (on ENST00000399302; = p.E537Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as COSV67899894; called by muse, mutect2, varscan2
- RABEP2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 36/146 reads (25%) | catalogued as COSV62868593, COSV62868842; called by muse, mutect2, varscan2
- RC3H1 | c.2553G>T p.Q851H | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV51198635; called by muse, mutect2, varscan2
- RGL2 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV65842065, COSV65842262; called by muse, mutect2
- RIMBP2 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 131/320 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55468057; called by muse, mutect2, varscan2
- RIMS2 | c.2809G>T p.G937W (on ENST00000666250 / NM_001348490.2; = p.G745W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51664331; called by muse, mutect2, varscan2
- RIPOR1 | c.331A>T p.K111* (on ENST00000379312 / NM_001193522.2; = p.K107* on NM_024519.4) | Nonsense Mutation (SNP) | VAF 47/206 reads (23%) | catalogued as COSV50218988; called by muse, mutect2, varscan2
- RNF138 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55233672; called by muse, mutect2, varscan2
- RNF26 | c.888G>C p.Q296H | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV60990049; called by muse, mutect2, varscan2
- ROBO2 | c.3714C>A p.D1238E | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59902780; called by muse, mutect2, varscan2
- RORB | c.517C>T p.Q173* (on ENST00000396204 / NM_001365023.1; = p.Q162* on NM_006914.4) | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV65334109; called by muse, mutect2, varscan2
- RORB | c.1231C>T p.H411Y (on ENST00000396204 / NM_001365023.1; = p.H400Y on NM_006914.4) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65334113; called by muse, mutect2, varscan2
- RP1 | c.4013T>C p.V1338A | Missense Mutation (SNP) | VAF 124/318 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.152); catalogued as COSV55112809; called by muse, mutect2, varscan2
- RUSF1 | c.1407A>T p.*469Cext*101 | Nonstop Mutation (SNP) | VAF 109/366 reads (30%) | catalogued as COSV57890677; called by muse, mutect2, varscan2
- RYR1 | c.3773G>T p.R1258L | Missense Mutation (SNP) | VAF 146/838 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs886054381, COSV62092838; ClinVar: uncertain significance; called by muse, varscan2
- S100A1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 151/929 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52679739; called by muse, mutect2, varscan2
- SACS | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66536815; called by muse, mutect2, varscan2
- SALL3 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778812708, COSV73305879, COSV73306109; called by muse, mutect2, varscan2
- SBNO1 | c.2951C>G p.S984* (on ENST00000420886; = p.S983* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 33/194 reads (17%) | catalogued as COSV57340048; called by muse, mutect2, varscan2
- SCGB2A2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.14); catalogued as rs372833801, COSV57174580; called by muse, mutect2, varscan2
- SCGB2A2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs941656689, COSV57174462; called by muse, mutect2, varscan2
- SCN1A | c.4954G>A p.G1652R (on ENST00000303395 / NM_001202435.3; = p.G1641R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as CM096107, COSV57664388; called by muse, mutect2, varscan2
- SCN1A | c.3347C>A p.P1116Q (on ENST00000303395 / NM_001202435.3; = p.P1105Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/304 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553540184, CD076902, COSV57664406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.3346C>A p.P1116T (on ENST00000303395 / NM_001202435.3; = p.P1105T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57664429; called by muse, mutect2, varscan2
- SCN9A | c.1912A>T p.M638L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV57604093; called by muse, mutect2, varscan2
- SDCCAG8 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV59406462; called by muse, mutect2, varscan2
- SEL1L2 | c.1994C>A p.P665Q | Missense Mutation (SNP) | VAF 78/358 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV53149494; called by muse, varscan2
- SEL1L2 | c.1993C>A p.P665T | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV53149511; called by muse, varscan2
- SEPHS1 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV59257619, COSV59258057; called by muse, mutect2, varscan2
- SF3B1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 108/318 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV59210262; called by muse, mutect2, varscan2
- SFTPA1 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 217/496 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs772993629, COSV64866789, COSV64867224; called by muse, mutect2, varscan2
- SH2D4A | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs776166138, COSV56121832; called by muse, mutect2, varscan2
- SIGLEC10 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 108/314 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59480074; called by muse, varscan2
- SIRT6 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs964309225, COSV59446831; called by muse, mutect2, varscan2
- SLC18A2 | c.953G>T p.W318L | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53689296; called by muse, mutect2, varscan2
- SLC26A3 | c.1497C>G p.I499M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60639363; called by muse, mutect2, varscan2
- SLC49A3 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs889580102, COSV59139777; called by muse, mutect2, varscan2
- SLC5A12 | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54820049; called by muse, mutect2, varscan2
- SLC9A9 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs759634686, COSV57221993; called by muse, mutect2
- SLITRK6 | c.1616C>A p.T539K | Missense Mutation (SNP) | VAF 102/143 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV68389678; called by muse, mutect2, varscan2
- SMC5 | c.2665-1G>C p.X889_splice | Splice Site (SNP) | VAF 24/32 reads (75%) | catalogued as COSV63192147; called by muse, mutect2, varscan2
- SPANXN1 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 187/241 reads (78%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.579); catalogued as COSV65122066; called by muse, mutect2, varscan2
- SPATA18 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 91/163 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs771291503, COSV54642640; called by muse, mutect2, varscan2
- SPATA19 | c.62T>A p.L21Q | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs201668593; called by muse, mutect2, varscan2
- SPOPL | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV54512499, COSV54512829; called by muse, mutect2, varscan2
- ST8SIA6 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV66466899; called by muse, mutect2, varscan2
- STEAP3 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV61528177; called by muse, mutect2
- STON1-GTF2A1L | c.2771C>A p.S924Y | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV59128041; called by muse, mutect2
- STON2 | c.2338G>T p.V780F (on ENST00000649389 / NM_001366849.2; = p.V723F on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV50843015; called by muse, mutect2
- STYXL2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.251); catalogued as rs150600224; called by muse, mutect2, varscan2
- SULF1 | c.2057A>T p.E686V | Missense Mutation (SNP) | VAF 168/377 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.209); catalogued as COSV52676801; called by muse, mutect2, varscan2
- SYNE1 | c.22219G>T p.A7407S (on ENST00000367255 / NM_182961.4; = p.A7336S on NM_033071.3) | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0.025); catalogued as COSV54935805; called by muse, mutect2, varscan2
- SYNE1 | c.22218G>T p.M7406I (on ENST00000367255 / NM_182961.4; = p.M7335I on NM_033071.3) | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV54935852; called by muse, mutect2, varscan2
- SYNJ1 | c.1553T>G p.L518W | Missense Mutation (SNP) | VAF 88/124 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59146048; called by muse, mutect2, varscan2
- TADA2B | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs201437381, COSV53826924; called by muse, mutect2, varscan2
- TDRD5 | c.637G>C p.A213P | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV54240377; called by muse, mutect2, varscan2
- TIA1 | c.989C>T p.P330L (on ENST00000433529 / NM_001351511.1; = p.P319L on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57006028; called by muse, mutect2, varscan2
- TMEM132D | c.1025T>C p.I342T | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV70598759; called by muse, mutect2, varscan2
- TNNC1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs796243470, COSV51766916; called by muse, mutect2, varscan2
- TPO | c.1861A>G p.K621E | Missense Mutation (SNP) | VAF 84/110 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV61097725; called by muse, mutect2, varscan2
- TRIM51 | c.1047C>A p.D349E | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV55264901; called by muse, varscan2
- TTN | c.102440C>T p.S34147F (on ENST00000591111; = p.S26723F on NM_003319.4) | Missense Mutation (SNP) | VAF 12/101 reads (12%) | PolyPhen possibly damaging (0.862); catalogued as COSV59949412; called by muse, mutect2, varscan2
- TTN | c.32719G>T p.E10907* (on ENST00000591111; = p.E9980* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/109 reads (39%) | catalogued as COSV59949439; called by muse, mutect2, varscan2
- UMOD | c.672C>A p.N224K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs868663806, COSV56774407; called by muse, mutect2
- USH2A | c.8768G>C p.G2923A | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56343062; called by muse, mutect2, varscan2
- USP13 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 128/680 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1392173484, COSV55863809; called by muse, mutect2, varscan2
- USP13 | c.2540G>T p.R847M | Missense Mutation (SNP) | VAF 60/1036 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV55863818; called by muse, mutect2
- UTRN | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs1159437562, COSV62330461; called by muse, mutect2, varscan2
- VSTM1 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 106/253 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV58074257; called by muse, mutect2, varscan2
- WDR81 | c.5299G>A p.V1767M (on ENST00000409644 / NM_001163809.2; = p.V716M on NM_152348.4) | Missense Mutation (SNP) | VAF 205/242 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1216937592, COSV58479979; called by muse, mutect2, varscan2
- WNT3A | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as rs548478697, COSV52729684; called by muse, mutect2, varscan2
- YPEL2 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as COSV57071186; called by muse, mutect2, varscan2
- ZCCHC8 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 177/495 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs753378950, COSV60317582; called by muse, mutect2, varscan2
- ZIM2 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as COSV55628924; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1334G>C p.G445A | Missense Mutation (SNP) | VAF 65/93 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1414862813, COSV56272103; called by muse, mutect2, varscan2
- ZNF208 | c.3565G>T p.V1189L | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV68102560; called by muse, mutect2, varscan2
- ZNF283 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61030771; called by muse, mutect2, varscan2
- ZNF292 | c.8035G>T p.E2679* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV60537012; called by muse, mutect2, varscan2
- ZNF518A | c.3065G>T p.C1022F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.735); catalogued as COSV60150747; called by muse, mutect2, varscan2
- ZNF536 | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62818547, COSV62821044; called by muse, mutect2, varscan2
- ZNF570 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV57578502; called by muse, mutect2
- BOP1 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- IGKV3-7 | c.205A>T p.I69F | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2
- KEAP1 | c.1406dup p.N469Kfs*11 | Frame Shift Ins (INS) | VAF 54/100 reads (54%) | called by mutect2, pindel, varscan2
- MTIF3 | c.203_204del p.T68Kfs*4 | Frame Shift Del (DEL) | VAF 43/321 reads (13%) | called by mutect2, pindel, varscan2
- POTEA | c.1073A>T p.N358I (on ENST00000519951 / NM_001005365.2; = p.N312I on NM_001002920.1) | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SIRPB1 | c.1153del p.V385Lfs*16 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel*, varscan2
- ST7L | c.643del p.E215Kfs*15 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- VN1R5 | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 120/466 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- XKR3 | c.1326C>G p.H442Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, mutect2
- AGT | c.522G>T p.R174= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as COSV64184139; called by muse, mutect2, varscan2
- ATP2B3 | c.2040G>A p.E680= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as COSV54842816; called by muse, mutect2
- ATRNL1 | c.3066C>T p.C1022= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV58079070; called by muse, mutect2, varscan2
- BARD1 | c.1674A>T p.S558= | Silent (SNP) | VAF 55/91 reads (60%) | catalogued as COSV53610131; called by muse, mutect2, varscan2
- BCL3 | c.1317A>T p.R439= | Silent (SNP) | VAF 94/392 reads (24%) | catalogued as COSV51233955; called by muse, mutect2, varscan2
- BMP6 | c.1038G>T p.L346= | Silent (SNP) | VAF 92/364 reads (25%) | catalogued as COSV51662508; called by muse, varscan2
- C11orf16 | c.1092A>G p.A364= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs1282653012, COSV58166713; called by muse, mutect2, varscan2
- C8A | c.882A>T p.T294= | Silent (SNP) | VAF 62/140 reads (44%) | catalogued as COSV63483422; called by muse, mutect2, varscan2
- CACNA1C | c.3816C>G p.A1272= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs1461465107, COSV100221874, COSV59705012; called by muse, mutect2, varscan2
- CACNA1E | c.6073C>A p.R2025= (on ENST00000367573 / NM_001205293.3; = p.R1982= on NM_000721.4) | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV62386040, COSV62386098; called by muse, mutect2, varscan2
- CADM3 | c.1008C>T p.I336= (on ENST00000368125 / NM_001127173.3; = p.I370= on NM_021189.5) | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs767354987, COSV63675782; called by muse, mutect2, varscan2
- CDH11 | c.867A>G p.R289= | Silent (SNP) | VAF 51/347 reads (15%) | catalogued as COSV51754995; called by muse, mutect2, varscan2
- CDH18 | c.237C>A p.S79= | Silent (SNP) | VAF 24/283 reads (8%) | catalogued as COSV56909903; called by muse, mutect2
- CEP192 | c.2145C>T p.I715= | Silent (SNP) | VAF 65/215 reads (30%) | catalogued as COSV58061697; called by muse, mutect2, varscan2
- CLTCL1 | c.1095G>C p.V365= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV54226867, COSV54227083; called by muse, mutect2
- CNTN3 | c.3021G>A p.S1007= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as rs1236515822, COSV55166121; called by muse, mutect2, varscan2
- COLEC12 | c.258G>C p.V86= | Silent (SNP) | VAF 47/174 reads (27%) | catalogued as COSV68369419; called by muse, mutect2, varscan2
- DENND10 | c.81G>T p.L27= | Silent (SNP) | VAF 82/315 reads (26%) | catalogued as COSV63857472; called by muse, mutect2, varscan2
- DNAJC1 | c.885T>C p.Y295= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs768985492, COSV65409846; called by muse, mutect2, varscan2
- DNMT3A | c.144G>T p.V48= | Silent (SNP) | VAF 58/215 reads (27%) | catalogued as COSV53044570; called by muse, mutect2, varscan2
- DOK3 | c.1179G>A p.L393= | Silent (SNP) | VAF 40/53 reads (75%) | catalogued as COSV100467462, COSV57251481; called by muse, mutect2, varscan2
- DPY19L2 | c.2211A>G p.E737= | Silent (SNP) | VAF 63/141 reads (45%) | catalogued as COSV61040331; called by muse, mutect2, varscan2
- EPHB1 | c.1824G>T p.R608= | Silent (SNP) | VAF 65/341 reads (19%) | catalogued as COSV67656595; called by muse, mutect2, varscan2
- ESRRA | c.141C>G p.L47= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV50005060; called by muse, mutect2, varscan2
- EXOC1 | c.1032C>T p.A344= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV62119584; called by muse, mutect2, varscan2
- FBN3 | c.8085C>T p.H2695= | Silent (SNP) | VAF 223/319 reads (70%) | catalogued as COSV54456382; called by muse, mutect2, varscan2
- FBXL3 | c.574C>T p.L192= | Silent (SNP) | VAF 32/209 reads (15%) | catalogued as COSV62918541; called by muse, mutect2, varscan2
- FLRT2 | c.882G>T p.G294= | Silent (SNP) | VAF 82/822 reads (10%) | catalogued as COSV58138383, COSV58141670; called by muse, mutect2, varscan2
- FLT3 | c.966A>G p.R322= | Silent (SNP) | VAF 34/360 reads (9%) | catalogued as COSV54048298; called by muse, mutect2
- FSCB | c.2259A>T p.V753= | Silent (SNP) | VAF 161/316 reads (51%) | catalogued as rs1163422334, COSV61217293; called by muse, mutect2, varscan2
- GLI3 | c.2946G>T p.G982= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV67886540; called by muse, mutect2, varscan2
- HEPH | c.3117T>C p.P1039= (on ENST00000343002; = p.P772= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/65 reads (77%) | catalogued as COSV57960908; called by muse, mutect2, varscan2
- IGLV2-14 | c.90T>A p.S30= | Silent (SNP) | VAF 271/814 reads (33%) | catalogued as rs768959184; called by muse, mutect2, varscan2
- IRAK3 | c.537A>T p.V179= | Silent (SNP) | VAF 55/164 reads (34%) | catalogued as COSV54160316, COSV54161593; called by muse, mutect2, varscan2
- JAK2 | c.2004C>T p.T668= | Silent (SNP) | VAF 72/233 reads (31%) | catalogued as COSV67593454; called by muse, mutect2, varscan2
- KCNK9 | c.558C>T p.F186= | Silent (SNP) | VAF 17/250 reads (7%) | catalogued as COSV57279549; called by muse, mutect2
- KCNQ2 | c.621G>A p.R207= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV60432663; called by muse, mutect2, varscan2
- KIF2B | c.141G>T p.T47= | Silent (SNP) | VAF 156/221 reads (71%) | catalogued as COSV52127788, COSV52128264, COSV52136589; called by muse, mutect2, varscan2
- KRT34 | c.1026G>A p.L342= | Silent (SNP) | VAF 148/176 reads (84%) | catalogued as COSV67449478; called by muse, mutect2, varscan2
- KRTAP1-1 | c.330A>G p.G110= | Silent (SNP) | VAF 70/92 reads (76%) | catalogued as COSV60398038; called by muse, mutect2, varscan2
- LAMA1 | c.4539G>T p.P1513= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs1447417989, COSV67533899, COSV67541787; called by muse, mutect2, varscan2
- LRRTM1 | c.1443T>C p.A481= | Silent (SNP) | VAF 70/293 reads (24%) | catalogued as COSV54439460; called by muse, varscan2
- LSAMP | c.888G>T p.L296= | Silent (SNP) | VAF 108/181 reads (60%) | catalogued as COSV61281693; called by muse, mutect2, varscan2
- MOGAT3 | c.603C>T p.V201= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as rs748533577, COSV56173286; called by muse, mutect2, varscan2
- MRGPRX1 | c.417A>G p.S139= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV57106407; called by muse, mutect2, varscan2
- MRGPRX4 | c.894G>A p.K298= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV58590149; called by muse, mutect2, varscan2
- MTIF3 | c.471G>C p.L157= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV63528508; called by muse, mutect2, varscan2
- MUC17 | c.8103C>G p.T2701= | Silent (SNP) | VAF 86/630 reads (14%) | catalogued as rs370237876; called by muse, mutect2, varscan2
- MYH15 | c.93C>G p.A31= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV56306515, COSV56321559; called by muse, mutect2, varscan2
- NLRP2 | c.1170C>A p.A390= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as COSV54753372; called by muse, mutect2, varscan2
- NPAS2 | c.846C>T p.T282= | Silent (SNP) | VAF 34/296 reads (11%) | catalogued as rs778023707, COSV59556338; called by muse, mutect2, varscan2
- NPBWR2 | c.801C>T p.A267= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs374344276; called by muse, mutect2, varscan2
- NRXN3 | c.825A>G p.P275= (on ENST00000557594 / NM_001272020.2; = p.P907= on NM_004796.6) | Silent (SNP) | VAF 63/193 reads (33%) | catalogued as rs746266528, COSV55320308; called by muse, mutect2, varscan2
- NSMAF | c.1947C>T p.S649= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as COSV50685013; called by muse, mutect2, varscan2
- OR1L4 | c.354T>C p.S118= | Silent (SNP) | VAF 53/265 reads (20%) | catalogued as COSV52340040; called by muse, varscan2
- OR52E6 | c.915G>A p.L305= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs540768482, COSV61431620; called by muse, mutect2, varscan2
- OR7G2 | c.228C>A p.L76= | Silent (SNP) | VAF 70/124 reads (56%) | catalogued as rs1568299280, COSV59687547; called by muse, mutect2, varscan2
- PAK3 | c.993C>T p.V331= (on ENST00000262836 / NM_001324328.2; = p.V316= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV53271950; called by muse, mutect2, varscan2
- PCDHA6 | c.1257G>C p.S419= | Silent (SNP) | VAF 77/579 reads (13%) | catalogued as COSV67039606, COSV67045719; called by muse, mutect2, varscan2
- PCDHGB1 | c.660C>T p.S220= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs1280314926, COSV53917520; called by muse, mutect2, varscan2
- PCDHGB4 | c.768C>T p.Y256= | Silent (SNP) | VAF 312/427 reads (73%) | catalogued as COSV53917529; called by muse, mutect2, varscan2
- PPP1R13B | c.2457C>T p.D819= | Silent (SNP) | VAF 13/221 reads (6%) | catalogued as COSV52449983; called by muse, mutect2
- PPP2R3A | c.2397T>A p.S799= | Silent (SNP) | VAF 297/418 reads (71%) | catalogued as COSV53861077; called by muse, mutect2, varscan2
- PPP4R4 | c.2232C>G p.P744= | Silent (SNP) | VAF 31/286 reads (11%) | catalogued as rs763468753, COSV58553117; called by muse, mutect2, varscan2
- PPP5C | c.501C>T p.I167= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs144237776; called by muse, mutect2
- SACS | c.1386T>A p.V462= | Silent (SNP) | VAF 57/85 reads (67%) | catalogued as COSV66536827; called by muse, mutect2, varscan2
- SETX | c.4068C>G p.P1356= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV56381116; called by muse, mutect2, varscan2
- SLC12A9 | c.231G>T p.L77= | Silent (SNP) | VAF 126/302 reads (42%) | catalogued as COSV51932156; called by muse, mutect2, varscan2
- SLC1A7 | c.561C>G p.V187= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV65194539; called by muse, mutect2, varscan2
- SLC9C2 | c.1185C>A p.L395= | Silent (SNP) | VAF 77/211 reads (36%) | catalogued as COSV62944593, COSV62949781; called by muse, mutect2, varscan2
- SLIT3 | c.1185G>T p.R395= | Silent (SNP) | VAF 359/530 reads (68%) | catalogued as COSV60597846, COSV60632717; called by muse, varscan2
- SMARCE1 | c.627G>A p.E209= | Silent (SNP) | VAF 181/217 reads (83%) | catalogued as COSV52860763; called by muse, mutect2, varscan2
- STRBP | c.198A>G p.K66= | Silent (SNP) | VAF 45/290 reads (16%) | catalogued as COSV62117395; called by muse, mutect2, varscan2
- TEK | c.3354T>C p.C1118= | Silent (SNP) | VAF 13/394 reads (3%) | catalogued as COSV66228153; called by muse, mutect2
- TLR10 | c.939C>T p.Y313= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs757323304, COSV58299535; called by muse, mutect2, varscan2
- TMEM108 | c.339G>T p.L113= | Silent (SNP) | VAF 37/262 reads (14%) | catalogued as COSV58866735; called by muse, mutect2, varscan2
- TNFAIP3 | c.441C>G p.L147= | Silent (SNP) | VAF 49/316 reads (16%) | catalogued as rs1354352671, COSV52797515; called by muse, mutect2, varscan2
- TRIP11 | c.2682A>G p.L894= | Silent (SNP) | VAF 193/319 reads (61%) | catalogued as COSV50915264; called by muse, mutect2, varscan2
- TXNDC11 | c.1311A>G p.A437= (on ENST00000356957 / NM_001303447.2; = p.A410= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs1196119487, COSV51597760; called by muse, mutect2, varscan2
- UBXN10 | c.135G>T p.R45= | Silent (SNP) | VAF 76/154 reads (49%) | catalogued as COSV66771924; called by muse, mutect2, varscan2
- USP34 | c.9816A>T p.L3272= | Silent (SNP) | VAF 350/523 reads (67%) | catalogued as COSV63724762; called by muse, mutect2, varscan2
- VIPAS39 | c.102G>A p.E34= | Silent (SNP) | VAF 98/772 reads (13%) | catalogued as COSV53631306; called by muse, mutect2, varscan2
- ZFP69 | c.258C>G p.T86= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV65528516; called by muse, mutect2, varscan2
- ZNF300 | c.51C>T p.F17= | Silent (SNP) | VAF 36/220 reads (16%) | catalogued as rs781506587, COSV99200082; called by muse, varscan2
- ZNF816 | c.1054C>A p.R352= | Silent (SNP) | VAF 76/502 reads (15%) | catalogued as rs535973683, COSV54410715, COSV54411371; called by muse, mutect2, varscan2
- ZP1 | c.105A>T p.P35= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV53923690; called by muse, varscan2
- ANK1 | c.5395-1092A>G | Intron (SNP) | VAF 34/87 reads (39%) | catalogued as COSV99226644; called by muse, mutect2, varscan2
- C12orf77 | n.333C>A | RNA (SNP) | VAF 67/173 reads (39%) | called by muse, mutect2, varscan2
- C1orf122 | c.*119C>T | 3'UTR (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100888704; called by muse, mutect2, varscan2
- ESRRB | c.1296+284G>T | Intron (SNP) | VAF 24/94 reads (26%) | catalogued as COSV99835719; called by muse, mutect2, varscan2
- ESRRB | c.1296+285G>T | Intron (SNP) | VAF 25/97 reads (26%) | catalogued as COSV99835723; called by muse, mutect2, varscan2
- MIR493 | n.71G>T | RNA (SNP) | VAF 30/260 reads (12%) | called by muse, varscan2
- OR2W5 | n.367C>A | RNA (SNP) | VAF 41/153 reads (27%) | called by muse, mutect2, varscan2
- PIK3CG | c.-1C>A | 5'UTR (SNP) | VAF 112/259 reads (43%) | catalogued as COSV100783139; called by muse, mutect2, varscan2
- SNORD115-23 | n.2G>C | RNA (SNP) | VAF 122/551 reads (22%) | called by muse, mutect2, varscan2
- SSPOP | n.936T>C | RNA (SNP) | VAF 87/301 reads (29%) | catalogued as COSV50486911; called by muse, mutect2, varscan2
- SSPOP | n.6017G>C | RNA (SNP) | VAF 8/28 reads (29%) | catalogued as COSV50486917; called by muse, mutect2, varscan2
- STARD7-AS1 | n.1390T>C | RNA (SNP) | VAF 48/100 reads (48%) | called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28580948 C>G | 3'Flank (SNP) | VAF 54/379 reads (14%) | catalogued as rs1310838724; called by muse, mutect2, varscan2
- TTN | c.10303+2564G>T | Intron (SNP) | VAF 23/92 reads (25%) | catalogued as rs548665458, COSV59949448; called by muse, mutect2, varscan2
- VNN3 | c.345-40C>A | Intron (SNP) | VAF 39/124 reads (31%) | catalogued as COSV99258662; called by muse, mutect2, varscan2
- VNN3 | c.345-2516A>T | Intron (SNP) | VAF 20/124 reads (16%) | catalogued as COSV51590485; called by muse, mutect2, varscan2
- VPS11 | c.-359G>T | 5'UTR (SNP) | VAF 37/77 reads (48%) | catalogued as rs539555921, COSV56184385; called by muse, mutect2, varscan2
- XIST | n.9829T>C | RNA (SNP) | VAF 126/143 reads (88%) | called by muse, mutect2, varscan2
